Somatic mutation profile of tumor specimen TCGA-TS-A7PB-01A (aliquot TCGA-TS-A7PB-01A-11D-A34C-32) from TCGA case TCGA-TS-A7PB, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 62.5 years (22,822 days).
Specimen TCGA-TS-A7PB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 885b437b-137e-4bb1-bb47-03f5abeddb6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7PB-10A (Blood Derived Normal), aliquot TCGA-TS-A7PB-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/028b3afd-f682-439b-912f-a87ad042df2f

The open-access MAF lists 35 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 20, Silent 10, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL121899.2 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs777514918; called by muse, mutect2, varscan2
- CLIP2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs782207729, COSV99791033; called by muse, mutect2, varscan2
- GATM | c.1217A>G p.H406R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67540133; called by muse, mutect2, varscan2
- GPRIN2 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs556360200; called by muse, mutect2, varscan2
- SLC38A10 | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs376751634; called by muse, mutect2, varscan2
- TBX21 | c.866C>T p.T289M | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1246392360; called by muse, mutect2, varscan2
- TLN1 | c.3095C>G p.A1032G | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as rs373243370; called by muse, mutect2, varscan2
- TRIM10 | c.1058G>A p.C353Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1175364922; called by muse, mutect2, varscan2
- TTN | c.20416G>A p.G6806R (on ENST00000591111; = p.G5879R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | PolyPhen probably damaging (0.995); catalogued as rs377229283, COSV59964525; called by muse, mutect2, varscan2
- ZNF544 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs370170869; called by muse, mutect2, varscan2
- DCTN1 | c.1994C>T p.A665V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- LRIT3 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 40/153 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LYST | c.6775_6788delinsA p.V2259Kfs*33 | Frame Shift Del (DEL) | VAF 33/137 reads (24%) | called by pindel, varscan2*
- MYCBP2 | c.561T>A p.S187R (on ENST00000357337; = p.S225R on NM_015057.5) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR10K1 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- PLAT | c.1082A>G p.E361G | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- PRKCA | c.143C>A p.T48N | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- RFC4 | c.826_827insA p.G276Efs*12 | Frame Shift Ins (INS) | VAF 32/111 reads (29%) | called by mutect2, pindel, varscan2
- RGL2 | c.2305G>A p.G769R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SETD2 | c.6424C>T p.Q2142* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- SH3RF2 | c.1517A>G p.Q506R | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SHROOM2 | c.4486G>A p.D1496N | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SLC44A2 | c.914T>G p.F305C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- TOMM40L | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- VPS13A | c.2237del p.F746Sfs*14 | Frame Shift Del (DEL) | VAF 62/248 reads (25%) | called by mutect2, pindel, varscan2
- BORA | c.1470G>A p.E490= (on ENST00000613797; = p.E415= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as rs769532231, COSV64695354; called by muse, mutect2, varscan2
- CBARP | c.105C>T p.I35= (on ENST00000382477; = p.I41= on NM_152769.3) | Silent (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- FAXDC2 | c.108C>T p.L36= | Silent (SNP) | VAF 23/70 reads (33%) | catalogued as rs1440171715; called by muse, mutect2, varscan2
- GRIK3 | c.714G>A p.A238= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as rs755346757, COSV100902484; called by muse, mutect2, varscan2
- LGALS8 | c.633C>G p.A211= (on ENST00000341872; = p.A253= on NM_006499.4) | Silent (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- MMP2 | c.1221C>T p.H407= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as rs772843973, COSV54599130; called by muse, mutect2
- PCDHA2 | c.2259G>A p.Q753= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- RFNG | c.543G>A p.E181= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs780990947; called by muse, mutect2, varscan2
- RTF2 | c.870C>G p.R290= | Silent (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- SV2C | c.216C>T p.D72= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as rs760204358, COSV59216333; called by muse, mutect2, varscan2
